Gene-level copy-number profile of tumor specimen TCGA-36-2543-01A from TCGA case TCGA-36-2543, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 85.5 years (31,211 days).
Specimen TCGA-36-2543-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.da6176df-e670-4160-885f-d7a5dd04d852.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-36-2543-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 823 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c8050d62-b4bc-4c0f-9dfb-1279a2869b8b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 65; copy number 1: 34; copy number 2: 20,463; copy number 3: 8,917; copy number 4: 22,978; copy number 5: 4,646; copy number 6: 2,367; copy number 7: 150; copy number 8: 120; copy number 9: 21; copy number 18: 39.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-36-2543-01A-01D-1043-01): tumor purity 0.58, ploidy 3.28, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 64 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:212,426,263–213,284,205, 13 genes: MIR548F2, AC093865.1, LINC01878, PCED1CP, AC108066.1, MIR4776-1, MIR4776-2, AC108066.2, IKZF2, AC079610.1, LINC01953, AC079610.2, SPAG16-DT.
- chr3:174,631,823–174,632,064, 1 gene: RN7SKP40.
- chr4:28,225,969–28,288,297, 1 gene: AC093791.2.
- chr5:59,528,861–59,703,703, 2 genes: NDUFB4P2, MIR582.
- chr5:138,868,921–139,293,557, 6 genes (within-gene range 0–2): LRRTM2, SIL1, RNA5SP194, AC011405.1, RPL12P21, RNU6-572P.
- chr5:139,274,102–139,284,899, 2 genes (within-gene range 0–2): SNHG4, SNORA74D.
- chr6:118,452,469–119,182,745, 14 genes: AL589993.1, CEP85L, BRD7P3, PLN, Z99496.1, SSXP10, SELENOKP3, MCM9, ASF1A, AL137009.1, FAM184A, Y_RNA, MIR548B, AL022722.2.
- chr6:120,015,179–120,015,257, 1 gene: MIR3144.
- chr6:125,370,034–125,761,269, 4 genes: AL450332.1, AL365259.1, LINC02523, HEY2.
- chr6:167,784,537–168,204,501, 10 genes: LINC01558, AL009178.2, AL009178.3, AFDN-DT, AFDN, HGC6.3, KIF25-AS1, KIF25, FRMD1, AL611929.1.
- chr7:110,590,082–110,592,204, 1 gene: AC073326.2.
- chr7:111,394,875–111,411,883, 2 genes: AC003989.2, AC003989.1.
- chr9:105,447,796–105,552,433, 2 genes (within-gene range 0–2): FSD1L, RALGAPA1P1.
- chr9:115,734,392–115,734,491, 1 gene: U2.
- chr14:32,879,246–32,882,830, 1 gene: AL049781.1.
- chr16:78,355,529–78,526,535, 3 genes: LSM3P5, AC046158.1, AC046158.4.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 60 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:104,738,597–105,115,019, 9 genes, copy number 9 (within-gene range 5–9): LHFPL3-AS1, AC091286.1, LHFPL3-AS2, RN7SL8P, AC007384.1, LINC01004, KMT2E-AS1, KMT2E, AC005070.3.
- chr7:139,230,356–139,777,998, 12 genes, copy number 9: UBN2, RNU6-206P, FMC1, LUC7L2, FMC1-LUC7L2, AC083880.1, RNU6-911P, KLRG2, AC005531.1, CLEC2L, ERHP1, HIPK2.
- chr20:31,257,664–31,952,046, 38 genes, copy number 18: DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1.
- chr20:31,970,181–31,970,831, 1 gene, copy number 18: AL031658.2.

Autosomal genes at a single copy (total copy number 1): 34. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
